Somatic mutation profile of tumor specimen C3L-04013-05 (aliquot CPT0233320006) from CPTAC case C3L-04013, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 61.6 years (22,508 days).
Specimen C3L-04013-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a4160c0-dc4f-4874-b863-06c3f83baea2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04013-31 (Blood Derived Normal), aliquot CPT0233440002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ebe05724-df5c-4d33-a21b-92eee0d06903

The open-access MAF lists 202 somatic variants for this specimen: 125 protein-altering or splice-affecting, 54 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 106, Silent 54, Intron 11, Nonsense Mutation 8, Frame Shift Del 6, 5'UTR 5, Splice Site 3, 3'UTR 3, RNA 2, Splice Region 1, Translation Start Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CASK | c.13G>T p.D5Y | Missense Mutation (SNP) | VAF 147/165 reads (89%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV59374752; called by muse, mutect2, varscan2
- CFH | c.104G>C p.G35A | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV62776859; called by muse, mutect2, varscan2
- CFHR5 | c.1478G>C p.R493T | Missense Mutation (SNP) | VAF 58/291 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.265); catalogued as COSV56828223; called by muse, mutect2, varscan2
- COL4A2 | c.3901C>T p.P1301S | Missense Mutation (SNP) | VAF 60/214 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs769564649; called by muse, mutect2, varscan2
- EPX | c.734T>A p.V245E | Missense Mutation (SNP) | VAF 189/360 reads (53%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.511); catalogued as rs1478339637; called by muse, mutect2, varscan2
- ERVV-2 | c.1345T>G p.S449A | Missense Mutation (SNP) | VAF 39/179 reads (22%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.722); catalogued as COSV74153448; called by muse, mutect2, varscan2
- FAT4 | c.5035C>T p.R1679C | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs569440986, COSV101272670; called by muse, mutect2, varscan2
- FRY | c.6517-1G>T p.X2173_splice | Splice Site (SNP) | VAF 38/112 reads (34%) | catalogued as COSV66581678; called by muse, mutect2, varscan2
- GOLM1 | c.164G>C p.R55T | Missense Mutation (SNP) | VAF 42/158 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57414102; called by muse, mutect2, varscan2
- GOSR1 | c.202G>C p.E68Q | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as COSV56718420; called by muse, mutect2, varscan2
- GRIK3 | c.1212G>A p.K404= | Splice Region (SNP) | VAF 46/124 reads (37%) | catalogued as rs1557703119; called by muse, mutect2, varscan2
- IQGAP1 | c.1321C>T p.P441S | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.019); catalogued as COSV51585675; called by muse, mutect2
- ITPRID1 | c.298G>T p.D100Y | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1373318482, COSV60074174; called by muse, mutect2, varscan2
- KCNG4 | c.1219G>T p.A407S | Missense Mutation (SNP) | VAF 129/168 reads (77%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as COSV57583271; called by muse, mutect2, varscan2
- KIAA2012 | c.31C>T p.H11Y | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.157); catalogued as rs112222412; called by muse, mutect2, varscan2
- LRP4 | c.532G>T p.D178Y | Missense Mutation (SNP) | VAF 236/441 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101066922; called by muse, mutect2, varscan2
- LYZL2 | c.395G>T p.G132V (on ENST00000375318; = p.G86V on NM_183058.3) | Missense Mutation (SNP) | VAF 129/254 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV100940513, COSV64684507; called by muse, mutect2, varscan2
- MUC5B | c.2985C>G p.I995M | Missense Mutation (SNP) | VAF 47/284 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV71592226; called by muse, mutect2, varscan2
- NOTCH1 | c.5019-1G>T p.X1673_splice | Splice Site (SNP) | VAF 104/444 reads (23%) | catalogued as COSV53071511; called by muse, mutect2, varscan2
- OBSCN | c.3301G>A p.A1101T | Missense Mutation (SNP) | VAF 98/492 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.855); catalogued as rs780907202; called by muse, mutect2, varscan2
- OR10G4 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 23/249 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs1477892267, COSV57979083; called by muse, mutect2, varscan2
- OR5AN1 | c.509G>C p.C170S | Missense Mutation (SNP) | VAF 41/194 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58322785; called by muse, mutect2, varscan2
- OR7D4 | c.605C>A p.A202D | Missense Mutation (SNP) | VAF 48/217 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV58072916; called by muse, mutect2, varscan2
- OR7G2 | c.555G>C p.L185F | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); catalogued as COSV59687406; called by muse, mutect2, varscan2
- PARS2 | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 98/229 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.071); catalogued as COSV64883791; called by muse, mutect2, varscan2
- PGR | c.1286C>A p.A429E | Missense Mutation (SNP) | VAF 129/254 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.551); catalogued as rs749208871; called by muse, mutect2, varscan2
- PKHD1L1 | c.6577G>T p.E2193* | Nonsense Mutation (SNP) | VAF 19/74 reads (26%) | catalogued as COSV65746567; called by muse, mutect2, varscan2
- PPID | c.121G>C p.V41L | Missense Mutation (SNP) | VAF 47/188 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as COSV100306815; called by muse, mutect2, varscan2
- RBMXL2 | c.662C>A p.S221* | Nonsense Mutation (SNP) | VAF 61/106 reads (58%) | catalogued as COSV100182482; called by muse, mutect2, varscan2
- RECQL5 | c.2614C>T p.R872C | Missense Mutation (SNP) | VAF 83/303 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as rs766331424; called by muse, mutect2, varscan2
- SAMD9L | c.2776G>A p.A926T | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.554); catalogued as rs566575234; called by muse, mutect2, varscan2
- SLC13A3 | c.250C>A p.Q84K | Missense Mutation (SNP) | VAF 27/255 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51717696; called by muse, mutect2, varscan2
- SNTG1 | c.668C>T p.T223I | Missense Mutation (SNP) | VAF 100/121 reads (83%) | SIFT deleterious (0.02); PolyPhen benign (0.193); catalogued as COSV99381054; called by muse, mutect2, varscan2
- TGFBI | c.596A>C p.N199T | Missense Mutation (SNP) | VAF 109/152 reads (72%) | SIFT tolerated (0.18); PolyPhen benign (0.079); catalogued as COSV59352318; called by muse, mutect2, varscan2
- THEMIS | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs891697397, COSV64070999; called by muse, mutect2, varscan2
- TMEM71 | c.794C>G p.S265* (on ENST00000523829 / NM_001382398.1; = p.S246* on NM_144649.3) | Nonsense Mutation (SNP) | VAF 23/97 reads (24%) | catalogued as COSV63458662, COSV63459863; called by muse, mutect2, varscan2
- TRRAP | c.2446C>T p.R816W | Missense Mutation (SNP) | VAF 96/371 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62842499; called by muse, mutect2, varscan2
- TTN | c.40543G>A p.D13515N (on ENST00000591111; = p.D6091N on NM_003319.4) | Missense Mutation (SNP) | VAF 74/230 reads (32%) | PolyPhen benign (0.015); catalogued as rs1375058579, COSV60435312; called by muse, mutect2, varscan2
- TXLNA | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 48/247 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as rs776873087; called by muse, mutect2, varscan2
- ZBTB38 | c.1313C>G p.S438C | Missense Mutation (SNP) | VAF 31/289 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.642); catalogued as rs776773942; called by muse, mutect2, varscan2
- A1CF | c.181G>A p.G61R | Missense Mutation (SNP) | VAF 72/198 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRG2 | c.1955C>G p.A652G (on ENST00000379869 / NM_001079858.3; = p.A649G on NM_005756.4) | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); called by muse, varscan2
- AFF3 | c.180C>A p.N60K | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- AGAP5 | c.746G>C p.R249P | Missense Mutation (SNP) | VAF 126/478 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- AHNAK | c.7518G>C p.W2506C | Missense Mutation (SNP) | VAF 54/419 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- AMZ1 | c.520T>C p.C174R | Missense Mutation (SNP) | VAF 118/401 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- ANK2 | c.3002C>A p.P1001Q | Missense Mutation (SNP) | VAF 107/367 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ANXA7 | c.1354G>T p.V452L (on ENST00000372919 / NM_001320880.2; = p.V430L on NM_001156.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- ARID4B | c.3007G>C p.E1003Q | Missense Mutation (SNP) | VAF 73/293 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ARID4B | c.2842G>C p.D948H | Missense Mutation (SNP) | VAF 46/229 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BMS1 | c.3505G>C p.A1169P | Missense Mutation (SNP) | VAF 123/256 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CARD6 | c.2588T>C p.V863A | Missense Mutation (SNP) | VAF 59/344 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CATIP | c.712G>T p.E238* | Nonsense Mutation (SNP) | VAF 45/202 reads (22%) | called by muse, mutect2, varscan2
- CCDC168 | c.15002C>T p.S5001L | Missense Mutation (SNP) | VAF 88/191 reads (46%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- CDHR2 | c.226A>C p.T76P | Missense Mutation (SNP) | VAF 59/135 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.907A>G p.I303V | Missense Mutation (SNP) | VAF 46/183 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.113); called by muse, varscan2
- CNTN4 | c.920G>A p.R307K | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- COL11A1 | c.573T>G p.D191E | Missense Mutation (SNP) | VAF 79/171 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CPZ | c.349C>A p.P117T (on ENST00000360986 / NM_001014447.3; = p.P106T on NM_003652.3) | Missense Mutation (SNP) | VAF 75/217 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRACD | c.93C>G p.N31K | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- CRACDL | c.871C>A p.P291T | Missense Mutation (SNP) | VAF 97/180 reads (54%) | SIFT tolerated (0.21); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- CSMD2 | c.10029G>T p.E3343D | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DAW1 | c.1215del p.S406Afs*12 | Frame Shift Del (DEL) | VAF 71/184 reads (39%) | called by mutect2, pindel, varscan2
- DCLRE1B | c.973C>T p.Q325* | Nonsense Mutation (SNP) | VAF 19/89 reads (21%) | called by muse, mutect2, varscan2
- DKK2 | c.113T>G p.I38S | Missense Mutation (SNP) | VAF 129/480 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- DMXL2 | c.1095C>A p.N365K | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- DOP1B | c.42C>G p.Y14* | Nonsense Mutation (SNP) | VAF 18/66 reads (27%) | called by muse, mutect2, varscan2
- DSCAM | c.917G>T p.G306V | Missense Mutation (SNP) | VAF 79/253 reads (31%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- EZH2 | c.1199A>G p.K400R (on ENST00000460911 / NM_001203247.2; = p.K405R on NM_004456.5) | Missense Mutation (SNP) | VAF 100/201 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- FBN1 | c.3311G>C p.G1104A | Missense Mutation (SNP) | VAF 113/462 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FBXO42 | c.728A>G p.K243R | Missense Mutation (SNP) | VAF 78/287 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- FIGN | c.2069G>T p.G690V | Missense Mutation (SNP) | VAF 94/172 reads (55%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FKBP7 | c.72G>C p.Q24H | Missense Mutation (SNP) | VAF 67/330 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- FLI1 | c.422G>T p.W141L | Missense Mutation (SNP) | VAF 54/166 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GET4 | c.718A>T p.I240F | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- GLYCTK | c.1047del p.L350Cfs*85 | Frame Shift Del (DEL) | VAF 28/86 reads (33%) | called by mutect2, pindel, varscan2
- GPAM | c.2479G>T p.V827L | Missense Mutation (SNP) | VAF 136/172 reads (79%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); called by muse, mutect2, varscan2
- HEATR1 | c.2053G>C p.E685Q | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.019); called by muse, mutect2
- IMPG1 | c.434G>A p.S145N | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IPO4 | c.2683_2684del p.Q895Vfs*60 | Frame Shift Del (DEL) | VAF 140/398 reads (35%) | called by mutect2, varscan2
- LAMC3 | c.1078G>A p.A360T | Missense Mutation (SNP) | VAF 341/613 reads (56%) | SIFT tolerated (0.89); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- LARP4B | c.323A>T p.H108L | Missense Mutation (SNP) | VAF 120/246 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MAP3K21 | c.731T>C p.I244T | Missense Mutation (SNP) | VAF 54/279 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MAT2A | c.159A>T p.K53N | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MLEC | c.525G>C p.K175N | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT tolerated (0.98); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MON2 | c.3014del p.G1005Efs*4 | Frame Shift Del (DEL) | VAF 80/350 reads (23%) | called by mutect2, pindel, varscan2
- MTPAP | c.246C>G p.C82W | Missense Mutation (SNP) | VAF 65/352 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- NEBL | c.2007G>A p.M669I | Missense Mutation (SNP) | VAF 88/487 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NME1 | c.104T>G p.L35R | Missense Mutation (SNP) | VAF 250/479 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- OR2AG1 | c.578C>G p.S193C | Missense Mutation (SNP) | VAF 58/218 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- OR2T27 | c.419T>C p.I140T | Missense Mutation (SNP) | VAF 63/201 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- PAPPA | c.2354T>C p.L785P | Missense Mutation (SNP) | VAF 79/283 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCBP1 | c.811T>C p.W271R | Missense Mutation (SNP) | VAF 56/205 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCDH9 | c.2848C>G p.L950V | Missense Mutation (SNP) | VAF 53/240 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- PCDHA8 | c.148C>A p.Q50K | Missense Mutation (SNP) | VAF 227/332 reads (68%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- PLCG1 | c.3406C>T p.L1136F | Missense Mutation (SNP) | VAF 32/638 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.209); called by muse, mutect2
- PRKAA1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 45/286 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRKCG | c.719T>G p.L240R | Missense Mutation (SNP) | VAF 68/383 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- PRR22 | c.948C>G p.D316E | Missense Mutation (SNP) | VAF 110/120 reads (92%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- PTPN13 | c.3086G>C p.S1029T | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- PTPRM | c.2104T>C p.F702L | Missense Mutation (SNP) | VAF 53/100 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- SEPTIN12 | c.378G>T p.W126C | Missense Mutation (SNP) | VAF 65/176 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SF3A1 | c.500T>C p.V167A | Missense Mutation (SNP) | VAF 81/202 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- SNPH | c.644A>T p.Y215F | Missense Mutation (SNP) | VAF 29/233 reads (12%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- SPAG1 | c.1387G>T p.E463* | Nonsense Mutation (SNP) | VAF 59/136 reads (43%) | called by muse, mutect2, varscan2
- SPEG | c.2387C>T p.A796V | Missense Mutation (SNP) | VAF 57/188 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- SPPL3 | c.112del p.M38Wfs*48 | Frame Shift Del (DEL) | VAF 22/95 reads (23%) | called by mutect2, pindel, varscan2
- ST6GALNAC3 | c.563C>A p.T188N | Missense Mutation (SNP) | VAF 31/103 reads (30%) | PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- TAPT1 | c.1157G>T p.R386L | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TBC1D16 | c.346A>T p.T116S | Missense Mutation (SNP) | VAF 54/95 reads (57%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- TCEA2 | c.871G>C p.E291Q | Missense Mutation (SNP) | VAF 43/307 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- TLE1 | c.560A>G p.D187G | Missense Mutation (SNP) | VAF 78/131 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TMX4 | c.463C>G p.L155V | Missense Mutation (SNP) | VAF 38/234 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.119); called by muse, mutect2
- TP53 | c.426_453del p.V143Rfs*18 | Frame Shift Del (DEL) | VAF 89/155 reads (57%) | called by mutect2, pindel, varscan2
- TRPM2 | c.787G>T p.E263* | Nonsense Mutation (SNP) | VAF 20/78 reads (26%) | called by muse, mutect2, varscan2
- TTN | c.34915A>G p.K11639E (on ENST00000591111; = p.K10712E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/255 reads (19%) | PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- WNT10B | c.394G>T p.V132L | Missense Mutation (SNP) | VAF 198/721 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- XIRP2 | c.6574C>A p.P2192T (on ENST00000628543; = p.P2367T on NM_152381.6) | Missense Mutation (SNP) | VAF 83/129 reads (64%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- ZBBX | c.1835A>T p.H612L | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.64); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZC3H6 | c.270A>T p.E90D | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- ZIC5 | c.1345C>A p.H449N | Missense Mutation (SNP) | VAF 418/513 reads (81%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ZNF333 | c.512-1G>A p.X171_splice | Splice Site (SNP) | VAF 126/150 reads (84%) | called by muse, varscan2
- ZNF519 | c.445T>A p.F149I | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF727 | c.751A>G p.T251A | Missense Mutation (SNP) | VAF 84/138 reads (61%) | SIFT tolerated (0.08); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- ZXDB | c.1978G>T p.V660L | Missense Mutation (SNP) | VAF 62/209 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AASDH | c.2145C>T p.N715= | Silent (SNP) | VAF 39/163 reads (24%) | called by muse, mutect2, varscan2
- ACE | c.1063C>A p.R355= | Silent (SNP) | VAF 147/243 reads (60%) | catalogued as COSV52008845; called by muse, mutect2, varscan2
- ADGRA3 | c.2718A>T p.A906= | Silent (SNP) | VAF 28/85 reads (33%) | called by muse, mutect2, varscan2
- ADGRG7 | c.201A>G p.E67= | Silent (SNP) | VAF 25/205 reads (12%) | catalogued as rs777619615; called by muse, mutect2, varscan2
- ANKRD52 | c.3105C>G p.L1035= | Silent (SNP) | VAF 82/358 reads (23%) | called by muse, mutect2, varscan2
- ANKRD54 | c.780C>T p.R260= | Silent (SNP) | VAF 112/149 reads (75%) | called by muse, mutect2, varscan2
- B3GALT6 | c.615C>G p.L205= | Silent (SNP) | VAF 62/156 reads (40%) | catalogued as rs775577008; called by muse, mutect2, varscan2
- B4GALT2 | c.330C>T p.I110= | Silent (SNP) | VAF 23/111 reads (21%) | catalogued as rs778561098, COSV99356708; called by muse, mutect2
- BCAN | c.1512G>A p.E504= | Silent (SNP) | VAF 30/169 reads (18%) | called by muse, mutect2, varscan2
- C1orf94 | c.750A>T p.T250= (on ENST00000488417 / NM_001134734.2; = p.T60= on NM_032884.5) | Silent (SNP) | VAF 69/282 reads (24%) | called by muse, mutect2, varscan2
- C6orf201 | c.303T>C p.N101= | Silent (SNP) | VAF 34/60 reads (57%) | called by muse, mutect2, varscan2
- CALHM4 | c.105C>G p.S35= | Silent (SNP) | VAF 102/253 reads (40%) | called by muse, mutect2, varscan2
- CARD9 | c.330C>T p.S110= | Silent (SNP) | VAF 109/389 reads (28%) | catalogued as rs375434244; called by muse, mutect2, varscan2
- CCDC168 | c.14307G>T p.L4769= | Silent (SNP) | VAF 181/476 reads (38%) | called by muse, mutect2, varscan2
- CEP135 | c.1536A>G p.L512= | Silent (SNP) | VAF 18/69 reads (26%) | called by muse, mutect2, varscan2
- CEP250 | c.4554G>A p.E1518= | Silent (SNP) | VAF 10/234 reads (4%) | called by muse, mutect2
- CES4A | c.951C>A p.S317= | Silent (SNP) | VAF 90/111 reads (81%) | called by muse, mutect2, varscan2
- CFAP74 | c.45C>T p.A15= | Silent (SNP) | VAF 88/244 reads (36%) | catalogued as rs768826653, COSV99574572; called by muse, mutect2, varscan2
- CROCC | c.1590G>A p.K530= | Silent (SNP) | VAF 38/90 reads (42%) | catalogued as rs749944892; called by muse, mutect2, varscan2
- CYFIP1 | c.2895C>T p.H965= | Silent (SNP) | VAF 48/202 reads (24%) | catalogued as rs141815988; called by muse, mutect2, varscan2
- DHRS7 | c.363T>C p.A121= | Silent (SNP) | VAF 23/189 reads (12%) | called by muse, mutect2, varscan2
- DNAH14 | c.7383A>C p.V2461= (on ENST00000445597; = p.V3114= on NM_001367479.1) | Silent (SNP) | VAF 31/142 reads (22%) | called by muse, mutect2
- EDC4 | c.2586A>G p.P862= | Silent (SNP) | VAF 152/215 reads (71%) | called by muse, mutect2, varscan2
- FAM83B | c.3036G>A p.*1012= | Silent (SNP) | VAF 11/26 reads (42%) | called by muse, mutect2, varscan2
- GBA3 | c.510T>A p.S170= | Silent (SNP) | VAF 80/229 reads (35%) | called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.90G>T p.V30= | Silent (SNP) | VAF 102/1236 reads (8%) | called by muse, mutect2
- IGHV3-43 | c.204T>C p.S68= | Silent (SNP) | VAF 112/259 reads (43%) | catalogued as rs141118925; called by muse, mutect2, varscan2
- KIF2C | c.594G>A p.V198= | Silent (SNP) | VAF 59/128 reads (46%) | catalogued as rs1557594953; called by muse, mutect2, varscan2
- KNTC1 | c.99A>G p.V33= | Silent (SNP) | VAF 30/107 reads (28%) | called by muse, mutect2, varscan2
- LAMC2 | c.153C>T p.F51= | Silent (SNP) | VAF 77/384 reads (20%) | catalogued as rs376424168; called by muse, mutect2, varscan2
- MAN1C1 | c.687C>G p.L229= | Silent (SNP) | VAF 75/335 reads (22%) | catalogued as rs756117687; called by muse, mutect2, varscan2
- MAT2B | c.948A>G p.K316= | Silent (SNP) | VAF 65/77 reads (84%) | called by muse, mutect2, varscan2
- MYH7 | c.3871C>T p.L1291= | Silent (SNP) | VAF 163/437 reads (37%) | called by muse, mutect2, varscan2
- NFATC1 | c.219G>A p.Q73= | Silent (SNP) | VAF 50/343 reads (15%) | called by muse, mutect2, varscan2
- NOTCH1 | c.5373C>T p.S1791= | Silent (SNP) | VAF 49/201 reads (24%) | catalogued as rs777013344, COSV53034550; ClinVar: likely benign; called by muse, mutect2, varscan2
- NPFFR1 | c.1056G>A p.P352= | Silent (SNP) | VAF 90/104 reads (87%) | catalogued as rs1476709234; called by muse, mutect2, varscan2
- OR2L8 | c.837C>A p.I279= | Silent (SNP) | VAF 116/287 reads (40%) | called by muse, mutect2, varscan2
- PACRG | c.307C>T p.L103= | Silent (SNP) | VAF 44/89 reads (49%) | called by muse, mutect2
- PAK4 | c.1536G>A p.E512= | Silent (SNP) | VAF 28/115 reads (24%) | catalogued as rs1260648444; called by muse, mutect2, varscan2
- PKD1L1 | c.5757C>A p.L1919= | Silent (SNP) | VAF 50/153 reads (33%) | called by muse, mutect2
- RP1 | c.2193C>T p.L731= | Silent (SNP) | VAF 49/149 reads (33%) | called by muse, mutect2, varscan2
- RYR2 | c.4174A>C p.R1392= | Silent (SNP) | VAF 34/174 reads (20%) | called by muse, mutect2, varscan2
- SHISA9 | c.450C>G p.T150= | Silent (SNP) | VAF 102/204 reads (50%) | called by muse, mutect2, varscan2
- SIGLEC15 | c.228G>T p.P76= | Silent (SNP) | VAF 146/840 reads (17%) | called by muse, mutect2, varscan2
- SLC17A1 | c.375C>A p.I125= | Silent (SNP) | VAF 42/216 reads (19%) | catalogued as COSV55081989; called by muse, mutect2, varscan2
- TCEAL5 | c.126G>T p.P42= | Silent (SNP) | VAF 121/135 reads (90%) | called by muse, mutect2, varscan2
- TFAP2B | c.120C>T p.L40= | Silent (SNP) | VAF 71/248 reads (29%) | catalogued as rs747403650; called by muse, mutect2, varscan2
- TMCO5A | c.210C>T p.T70= | Silent (SNP) | VAF 101/185 reads (55%) | called by muse, mutect2, varscan2
- TNRC6B | c.1317A>G p.G439= | Silent (SNP) | VAF 63/201 reads (31%) | catalogued as rs17001766; called by muse, mutect2, varscan2
- VSTM2B | c.669G>A p.A223= | Silent (SNP) | VAF 304/472 reads (64%) | called by muse, mutect2, varscan2
- XIRP1 | c.174C>T p.Y58= | Silent (SNP) | VAF 64/77 reads (83%) | called by muse, mutect2, varscan2
- ZNF469 | c.4197A>G p.P1399= (on ENST00000437464; = p.P1427= on NM_001367624.2) | Silent (SNP) | VAF 128/170 reads (75%) | catalogued as rs1217148465; called by muse, mutect2, varscan2
- ZNF540 | c.1113T>A p.T371= | Silent (SNP) | VAF 104/243 reads (43%) | called by muse, mutect2, varscan2
- ZNF785 | c.726C>T p.S242= | Silent (SNP) | VAF 107/380 reads (28%) | called by muse, mutect2, varscan2
- AC092118.1 | n.1108G>T | RNA (SNP) | VAF 89/106 reads (84%) | called by muse, mutect2, varscan2
- ANKRD26 | c.1635+2102A>G | Intron (SNP) | VAF 23/153 reads (15%) | called by muse, mutect2, varscan2
- ASH1L | c.-432C>T | 5'UTR (SNP) | VAF 84/408 reads (21%) | catalogued as rs1179305183; called by muse, varscan2
- ATP10A | c.449+410G>C | Intron (SNP) | VAF 37/146 reads (25%) | called by muse, mutect2, varscan2
- CARD8 | chr19:48204190 G>C | 3'Flank (SNP) | VAF 35/197 reads (18%) | called by muse, mutect2, varscan2
- DUSP22 | c.-99G>T | 5'UTR (SNP) | VAF 43/276 reads (16%) | called by muse, mutect2, varscan2
- ETV2 | c.829-20C>A | Intron (SNP) | VAF 16/99 reads (16%) | catalogued as rs765942147, COSV55838694; called by muse, mutect2, varscan2
- H2BP2 | n.1061+1856G>A | Intron (SNP) | VAF 265/620 reads (43%) | called by muse, mutect2, varscan2
- IL10RA | c.-60G>A | 5'UTR (SNP) | VAF 104/209 reads (50%) | called by muse, mutect2, varscan2
- LIN7A | c.483+3637C>G | Intron (SNP) | VAF 18/71 reads (25%) | called by muse, mutect2, varscan2
- MACROD2 | c.*9A>T | 3'UTR (SNP) | VAF 112/185 reads (61%) | called by muse, mutect2, varscan2
- MEG3 | n.1160C>T | RNA (SNP) | VAF 67/196 reads (34%) | catalogued as rs926727637; called by muse, mutect2, varscan2
- MYL1 | c.-36T>A | 5'UTR (SNP) | VAF 25/103 reads (24%) | called by muse, varscan2
- NRXN1 | c.3719-1391T>C | Intron (SNP) | VAF 41/162 reads (25%) | called by muse, mutect2, varscan2
- POLE | c.6658-270C>T | Intron (SNP) | VAF 39/143 reads (27%) | called by muse, mutect2, varscan2
- PRKD2 | c.2338+29G>T | Intron (SNP) | VAF 50/178 reads (28%) | called by muse, varscan2
- RALBP1 | c.*709C>T | 3'UTR (SNP) | VAF 101/150 reads (67%) | called by muse, mutect2, varscan2
- RO60 | c.580+935C>T | Intron (SNP) | VAF 10/52 reads (19%) | catalogued as rs1048968217; called by muse, varscan2
- SLC25A17 | c.-22G>A | 5'UTR (SNP) | VAF 54/145 reads (37%) | called by muse, mutect2, varscan2
- SPINT4 | c.*3G>T | 3'UTR (SNP) | VAF 32/328 reads (10%) | called by muse, mutect2, varscan2
- TECR | c.799+39C>T | Intron (SNP) | VAF 166/529 reads (31%) | called by muse, mutect2, varscan2
- WT1 | chr11:32438343 G>C | 5'Flank (SNP) | VAF 39/127 reads (31%) | called by muse, mutect2, varscan2
- ZFHX3 | c.-897+3510C>T | Intron (SNP) | VAF 58/158 reads (37%) | catalogued as rs1341270270; called by muse, mutect2, varscan2
